Somatic mutation profile of tumor specimen TCGA-PK-A5HC-01A (aliquot TCGA-PK-A5HC-01A-11D-A30A-10) from TCGA case TCGA-PK-A5HC, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 44.3 years (16,182 days).
Specimen TCGA-PK-A5HC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b81f85df-e396-4ea9-8bb1-0b1965d12355.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-PK-A5HC-11A (Solid Tissue Normal), aliquot TCGA-PK-A5HC-11A-11D-A30A-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b01c5781-bed9-4b81-9393-da3fb12b8698

The open-access MAF lists 66 somatic variants for this specimen: 48 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 17, Frame Shift Ins 2, RNA 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.216dup p.V73Rfs*76 | Frame Shift Ins (INS) | VAF 37/63 reads (59%) | catalogued as rs730882018, COSV104369723; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ARHGEF28 | c.2784C>G p.I928M | Missense Mutation (SNP) | VAF 59/216 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs535664718, COSV55254460; called by muse, mutect2, varscan2
- CADPS | c.1285G>C p.E429Q | Missense Mutation (SNP) | VAF 48/195 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV51872900; called by muse, mutect2, varscan2
- CARNMT1 | c.467A>G p.D156G | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as rs1289237160; called by muse, mutect2
- CD1E | c.77C>A p.S26Y | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.67); PolyPhen benign (0.074); catalogued as rs1198580609; called by muse, mutect2, varscan2
- CNGB3 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.041); catalogued as rs373216514, COSV60686637; called by muse, mutect2, varscan2
- COL19A1 | c.2718G>T p.E906D | Missense Mutation (SNP) | VAF 30/202 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV100507236; called by muse, mutect2, varscan2
- FNIP1 | c.2773dup p.I925Nfs*6 | Frame Shift Ins (INS) | VAF 24/70 reads (34%) | catalogued as rs1386424977; called by mutect2, varscan2
- OR6K6 | c.825C>A p.F275L (on ENST00000368144; = p.F251L on NM_001005184.1) | Missense Mutation (SNP) | VAF 82/358 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.967); catalogued as COSV63744677; called by muse, mutect2, varscan2
- PAPPA | c.1804G>T p.D602Y | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60293242; called by muse, mutect2, varscan2
- PI4KA | c.5551G>C p.V1851L | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs2539908; called by muse, mutect2
- PNPLA4 | c.181-1G>A p.X61_splice | Splice Site (SNP) | VAF 16/104 reads (15%) | catalogued as rs1370329956; called by muse, mutect2, varscan2
- PPFIA3 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 123/430 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100494757; called by muse, mutect2, varscan2
- PRKAG2 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs775756069, COSV99835714; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SNRNP200 | c.1466A>G p.Y489C | Missense Mutation (SNP) | VAF 80/247 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.072); catalogued as rs1259944697; called by muse, mutect2, varscan2
- TMC5 | c.90G>T p.L30F | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.424); catalogued as COSV66864578; called by muse, mutect2, varscan2
- ZNF184 | c.2237G>A p.R746K | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.46); catalogued as rs757885444, COSV53005826; called by muse, mutect2, varscan2
- ACTN2 | c.1085C>T p.P362L | Missense Mutation (SNP) | VAF 57/208 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AHNAK2 | c.7414G>C p.A2472P | Missense Mutation (SNP) | VAF 57/161 reads (35%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ANKRD17 | c.1762G>T p.A588S | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- ASCC3 | c.1326G>C p.R442S | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP13A5 | c.1861G>T p.V621F | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- DGLUCY | c.842C>A p.P281H | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FAM167A | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- GAS2L2 | c.1256C>G p.S419C | Missense Mutation (SNP) | VAF 54/111 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- HNRNPLL | c.935C>A p.P312H | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- IFI16 | c.1928A>T p.E643V (on ENST00000295809 / NM_001364867.2; = p.E587V on NM_005531.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KMT2A | c.8228G>C p.R2743T | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- MMUT | c.1383G>C p.E461D | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MUC16 | c.30985C>T p.P10329S | Missense Mutation (SNP) | VAF 8/248 reads (3%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.005); called by muse, mutect2
- MUC16 | c.1488C>A p.S496R | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- MYLK | c.3708G>A p.M1236I | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- OR2G6 | c.191G>T p.S64I | Missense Mutation (SNP) | VAF 47/197 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- OR5AR1 | c.653A>G p.Y218C | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- PCDHB5 | c.47T>G p.F16C | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- PHRF1 | c.3009G>C p.K1003N (on ENST00000264555 / NM_001286581.2; = p.K1002N on NM_020901.4) | Missense Mutation (SNP) | VAF 61/180 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- PIAS2 | c.633G>T p.L211F | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); called by muse, mutect2
- PPM1H | c.882C>G p.I294M | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- PRUNE2 | c.709G>C p.D237H | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTBP2 | c.1150G>A p.D384N (on ENST00000426398 / NM_001300986.2; = p.D376N on NM_021190.4) | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- RAB3GAP2 | c.835G>C p.D279H | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- SIGLEC12 | c.446C>G p.S149* (on ENST00000291707 / NM_053003.4; = p.S31* on NM_033329.2) | Nonsense Mutation (SNP) | VAF 57/235 reads (24%) | called by muse, mutect2, varscan2
- SLC35G6 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 40/194 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- SYTL4 | c.447A>T p.R149S | Missense Mutation (SNP) | VAF 40/63 reads (63%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- TCOF1 | c.2564C>G p.A855G (on ENST00000377797 / NM_001135243.1; = p.A778G on NM_000356.4) | Missense Mutation (SNP) | VAF 77/320 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- TMC5 | c.2097C>G p.I699M (on ENST00000396229 / NM_001105248.1; = p.I453M on NM_024780.5) | Missense Mutation (SNP) | VAF 45/192 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- TNFRSF21 | c.1851G>T p.E617D | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- UTP11 | c.102G>T p.K34N | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ADH5 | c.936C>T p.R312= | Silent (SNP) | VAF 50/662 reads (8%) | called by muse, mutect2
- ADRB3 | c.363G>T p.V121= | Silent (SNP) | VAF 113/303 reads (37%) | called by muse, mutect2, varscan2
- CCSER1 | c.1462T>C p.L488= | Silent (SNP) | VAF 9/121 reads (7%) | called by muse, mutect2
- CYP21A2 | c.618C>G p.S206= | Silent (SNP) | VAF 115/478 reads (24%) | called by muse, mutect2, varscan2
- ENAM | c.3381G>T p.G1127= | Silent (SNP) | VAF 84/514 reads (16%) | called by muse, mutect2, varscan2
- GATA6 | c.1776G>C p.L592= | Silent (SNP) | VAF 14/84 reads (17%) | called by muse, mutect2
- HERC2 | c.1818C>T p.I606= | Silent (SNP) | VAF 97/230 reads (42%) | catalogued as rs139612007; called by muse, mutect2, varscan2
- HK3 | c.345G>T p.G115= | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as rs753400254, COSV52838001; called by muse, mutect2, varscan2
- IGSF21 | c.741C>T p.S247= | Silent (SNP) | VAF 28/311 reads (9%) | catalogued as rs1467591913, COSV52147171; called by muse, mutect2
- INTU | c.1374G>A p.Q458= | Silent (SNP) | VAF 21/104 reads (20%) | called by muse, mutect2, varscan2
- MYOM1 | c.4518G>A p.K1506= | Silent (SNP) | VAF 24/117 reads (21%) | called by muse, mutect2, varscan2
- PCDHA8 | c.2112C>A p.I704= | Silent (SNP) | VAF 27/260 reads (10%) | catalogued as COSV100969228; called by muse, mutect2, varscan2
- PCNX2 | c.2346G>T p.S782= | Silent (SNP) | VAF 12/130 reads (9%) | called by muse, mutect2
- SGO2 | c.3756C>T p.F1252= | Silent (SNP) | VAF 31/102 reads (30%) | called by muse, mutect2, varscan2
- SMO | c.1845C>T p.S615= | Silent (SNP) | VAF 38/131 reads (29%) | catalogued as rs540111843; called by muse, mutect2, varscan2
- TYRO3 | c.273C>T p.I91= | Silent (SNP) | VAF 58/137 reads (42%) | called by muse, mutect2, varscan2
- XIRP2 | c.6235C>T p.L2079= (on ENST00000628543; = p.L2254= on NM_152381.6) | Silent (SNP) | VAF 49/153 reads (32%) | called by muse, mutect2, varscan2
- OR2U1P | n.378G>C | RNA (SNP) | VAF 55/141 reads (39%) | called by muse, mutect2, varscan2
